Gene-level copy-number profile of tumor specimen ALCH-B1TI-TTP1-A from ALCHEMIST case ALCH-B1TI, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 61.1 years (22,309 days).
Specimen ALCH-B1TI-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 506552ac-127b-4982-9888-355aad8c3658.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1TI-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,234 have no estimate.
https://portal.gdc.cancer.gov/files/5c6b39ea-96f4-42ec-8345-a5c219e0455f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 85; copy number 1: 2,213; copy number 2: 55,539; copy number 3: 526; copy number 4: 12; copy number 5: 9; copy number 7: 4; copy number 8: 1.

Homozygous deletions (total copy number 0; autosomes only): 79 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:30,409,560–30,411,638, 1 gene: AL161638.2.
- chr9:125,417,305–125,417,586, 1 gene: Metazoa_SRP.
- chr10:43,077,064–43,130,351, 1 gene: RET.
- chr12:123,010,667–123,010,728, 1 gene (within-gene range 0–2): MIR4304.
- chr14:101,552,221–101,563,452, 3 genes: DIO3OS, MIR1247, DIO3.
- chr15:25,170,723–25,250,940, 44 genes (within-gene range 0–2): SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr15:41,825,099–41,848,155, 4 genes (within-gene range 0–2): AC020659.2, JMJD7, JMJD7-PLA2G4B, PLA2G4B.
- chr15:85,744,109–85,794,925, 6 genes (within-gene range 0–2): AC021739.2, AC021739.4, LINC02883, KLHL25, MIR1276, AC021739.1.
- chr16:67,164,681–67,198,918, 5 genes (within-gene range 0–12): HSF4, NOL3, KIAA0895L, EXOC3L1, E2F4.
- chr17:30,624,413–30,637,466, 2 genes (within-gene range 0–1): SH3GL1P2, LRRC37BP1.
- chr17:61,361,668–61,411,555, 4 genes (within-gene range 0–2): AC005746.2, AC005746.1, TBX2-AS1, TBX2.
- chr22:18,533,646–18,611,919, 4 genes: PI4KAP1, AC023490.1, RN7SKP131, RIMBP3.
- chr22:29,705,256–29,731,833, 3 genes (within-gene range 0–2): AC004882.1, AC004882.2, CABP7.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 14 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:37,032–37,477, 1 gene, copy number 8: AC215522.1.
- chr11:64,764,606–64,778,786, 1 gene, copy number 7: SF1.
- chr16:28,379,579–28,415,018, 3 genes, copy number 7: EIF3CL, MIR6862-1, CDC37P2.
- chr22:18,178,038–18,345,899, 2 genes, copy number 5: FAM230D, GGTLC5P.
- chr22:18,400,407–18,518,161, 5 genes, copy number 5: PPP1R26P3, FAM230A, AC023490.2, FAM247B, GGTLC3.
- chr22:49,960,768–49,964,072, 2 genes, copy number 5: PIM3, MIR6821.

Autosomal genes at a single copy (total copy number 1): 2,213. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
